Somatic mutation profile of tumor specimen TCGA-5P-A9K3-01A (aliquot TCGA-5P-A9K3-01A-11D-A42J-10) from TCGA case TCGA-5P-A9K3, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 59.8 years (21,829 days).
Specimen TCGA-5P-A9K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26532a1d-d0ff-45b0-a964-44552b969d86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9K3-10A (Blood Derived Normal), aliquot TCGA-5P-A9K3-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eae8b06a-7152-4f04-b32a-910b9252161c

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 45, Silent 13, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 133/257 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 239/506 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 68/115 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519997, CX942126, COSV52676090, COSV52699193, COSV52985195; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.644T>G p.F215C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); catalogued as COSV101239071; called by muse, mutect2, varscan2
- ADD1 | c.1979A>G p.K660R | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV99296170; called by muse, mutect2, varscan2
- ANKH | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs148526515; called by muse, mutect2, varscan2
- ANKS1A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100832184; called by muse, mutect2, varscan2
- BPNT1 | c.779-1G>C p.X260_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100435606; called by muse, mutect2, varscan2
- CALR | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV100330524; called by muse, mutect2
- CASP6 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 126/213 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs376919922, COSV99488619; called by muse, mutect2, varscan2
- CLEC1A | c.96T>G p.H32Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100191253; called by muse, mutect2, varscan2
- COL6A6 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs1243198563, COSV100650028; called by muse, mutect2, varscan2
- CTCF | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs761623880, COSV99864731; called by muse, mutect2, varscan2
- CYP51A1 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99133681; called by muse, mutect2, varscan2
- DNAH8 | c.11641A>T p.I3881F | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100543987; called by muse, mutect2, varscan2
- ESF1 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99176295; called by muse, mutect2, varscan2
- FANCB | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 88/116 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1555904350, COSV100146459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO47 | c.980T>A p.L327H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100960606, COSV65242140; called by muse, mutect2, varscan2
- GBP2 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV100975359; called by muse, mutect2, varscan2
- GIN1 | c.1471A>G p.T491A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV101204286; called by muse, mutect2, varscan2
- GPKOW | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 165/212 reads (78%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99332543; called by muse, mutect2, varscan2
- KCNT2 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 183/518 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV54088756, COSV99652398; called by muse, mutect2, varscan2
- LAMA3 | c.9605C>T p.P3202L (on ENST00000313654 / NM_198129.4; = p.P1593L on NM_000227.6) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99334230; called by muse, mutect2, varscan2
- LRFN4 | c.1601C>G p.T534S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV100540735; called by muse, mutect2, varscan2
- LRRC32 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1255197170, COSV52632602; called by muse, mutect2, varscan2
- MOV10L1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV53170643, COSV99432937; called by muse, varscan2
- MYCBP2 | c.5872A>G p.N1958D (on ENST00000357337; = p.N1996D on NM_015057.5) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV100629588; called by muse, mutect2, varscan2
- MYO7A | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV101289082; called by muse, mutect2, varscan2
- NLRP7 | c.1703T>A p.L568Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100051950; called by muse, mutect2, varscan2
- NRXN2 | c.2588G>A p.G863D | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99633117; called by muse, mutect2, varscan2
- P2RX6 | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV99488575; called by muse, mutect2, varscan2
- PDZD8 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV57823021, COSV57825453; called by muse, mutect2, varscan2
- PGLYRP2 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV99483889; called by muse, mutect2, varscan2
- PKD2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 126/220 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV99417063; called by muse, varscan2
- PKHD1 | c.10505A>T p.E3502V | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1554183496, CM032337, COSV100944026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLD4 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as COSV101190472; called by muse, mutect2, varscan2
- PRX | c.3343G>T p.A1115S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV99396475; called by muse, mutect2, varscan2
- RAB40B | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99483543; called by muse, mutect2, varscan2
- RNF19A | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100347502; called by muse, mutect2, varscan2
- SART1 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100408909; called by muse, mutect2, varscan2
- SETD2 | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100338422, COSV57447780; called by muse, mutect2, varscan2
- SMARCA1 | c.3117G>C p.K1039N | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV100946437; called by muse, mutect2, varscan2
- TCP10L | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs751306916, COSV100291830; called by muse, mutect2, varscan2
- THSD4 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs374464107; called by muse, mutect2, varscan2
- TNXB | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs779419589, COSV100926060; called by muse, mutect2, varscan2
- TRPM7 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.255); catalogued as COSV100539568; called by muse, mutect2, varscan2
- TTN | c.22441G>A p.V7481M (on ENST00000591111; = p.V6554M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | PolyPhen possibly damaging (0.638); catalogued as rs144032104; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ZNF92 | c.880T>A p.F294I (on ENST00000328747 / NM_152626.4; = p.F225I on NM_007139.4) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100165717; called by muse, mutect2, varscan2
- BTG2 | c.406dup p.T136Nfs*40 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- FKBP11 | c.357_358del p.Y119* | Nonsense Mutation (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- NLGN1 | c.1380del p.F460Lfs*11 | Frame Shift Del (DEL) | VAF 46/186 reads (25%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3419del p.N1140Mfs*19 (on ENST00000296302 / NM_001366071.2; = p.N1115Mfs*19 on NM_018313.5) | Frame Shift Del (DEL) | VAF 52/92 reads (57%) | called by mutect2, pindel, varscan2
- PPP1R16A | c.1521_1522dup p.L508Rfs*88 | Frame Shift Ins (INS) | VAF 34/119 reads (29%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.1511del p.P504Rfs*11 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- SLC2A13 | c.894_905del p.N298_E302delinsK | In Frame Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- TCF25 | c.16dup p.L6Pfs*25 | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- ADAM33 | c.1836C>G p.L612= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100597748; called by muse, mutect2, varscan2
- AJM1 | c.2391C>T p.R797= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99915532; called by muse, mutect2, varscan2
- CKMT1B | c.699G>A p.P233= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs776227809; called by muse, varscan2
- CNNM2 | c.504C>T p.R168= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV100881673; called by muse, mutect2, varscan2
- COL6A2 | c.2373C>T p.D791= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56005373; called by muse, mutect2, varscan2
- EP300 | c.1497T>C p.S499= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99607838; called by muse, mutect2, varscan2
- HMCN1 | c.10704C>G p.P3568= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as COSV99626066; called by muse, mutect2, varscan2
- NIN | c.5350C>A p.R1784= (on ENST00000382041 / NM_182946.1; = p.R1071= on NM_016350.4) | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV99812486; called by muse, mutect2, varscan2
- PPP1R12A | c.2679T>C p.S893= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99700126; called by muse, mutect2, varscan2
- TRIM4 | c.234C>T p.R78= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100458391; called by muse, mutect2, varscan2
- TUBB1 | c.1137T>C p.N379= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99413972; called by muse, mutect2, varscan2
- ZNF16 | c.585C>T p.D195= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99429487; called by muse, mutect2, varscan2
- ZNF583 | c.1515A>T p.G505= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99382013; called by muse, mutect2
